Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046468-09A.1 (aliquot TARGET-15-SJMPAL046468-09A.1-01D) from TARGET case TARGET-15-SJMPAL046468, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.9 years (5,809 days).
Specimen TARGET-15-SJMPAL046468-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eee74dbb-1f88-4899-bd32-6f5a66bde2f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046468-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL046468-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca8ff8ef-bc80-467d-8e40-529b966fb578

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 5, In Frame Del 2, Nonsense Mutation 1, In Frame Ins 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.181G>T p.D61Y | Missense Mutation (SNP) | VAF 66/124 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs397507510, CD055729, CM021127, CM101143, COSV61004841, COSV61006072, COSV61006164; ClinVar: pathogenic; called by muse, varscan2
- FAM133A | c.307C>T p.R103W | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.231); catalogued as rs374525042; called by muse, mutect2, varscan2
- HOXC4 | c.752C>A p.T251K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0.049); catalogued as COSV57699912; called by muse, mutect2
- MAMLD1 | c.1790A>T p.Q597L | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.529); catalogued as COSV53376712; called by muse, mutect2
- MAST4 | c.4733C>T p.P1578L (on ENST00000403625 / NM_001164664.2; = p.P1389L on NM_015183.3) | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as rs979897084; called by muse, mutect2, varscan2
- PAN3 | c.1202C>T p.T401M | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1178592350, COSV56706097; called by muse, mutect2, varscan2
- PAX5 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63905332; called by muse, mutect2, varscan2
- PGM2L1 | c.386G>T p.R129M | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV104402517; called by muse, mutect2
- RRAS2 | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV56329798, COSV56330700, COSV56332575; called by muse, varscan2
- ARID4B | c.3716_3727del p.K1239_E1242del | In Frame Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, varscan2
- B3GALT6 | c.662C>A p.S221* | Nonsense Mutation (SNP) | VAF 3/14 reads (21%) | called by muse, mutect2
- C7orf25 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CNTLN | c.2578C>A p.L860I | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.055); called by muse, mutect2
- CREBBP | c.3238_3239insG p.P1080Rfs*7 | Frame Shift Ins (INS) | VAF 17/121 reads (14%) | called by mutect2, pindel, varscan2
- CYP4B1 | c.498C>A p.D166E | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.35); called by muse, mutect2
- FRMPD2 | c.3325G>A p.V1109M | Missense Mutation (SNP) | VAF 15/23 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); called by mutect2, varscan2
- GFI1 | c.1139G>T p.S380I | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- PARP10 | c.2792G>T p.R931L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.141); called by muse, mutect2
- PAX5 | c.173T>C p.L58P | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SOWAHB | c.1838G>T p.W613L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- UNC5B | c.205_206insTCT p.R68_C69insF | In Frame Ins (INS) | VAF 45/108 reads (42%) | called by mutect2, pindel, varscan2
- XIRP2 | c.4564G>A p.E1522K (on ENST00000628543; = p.E1697K on NM_152381.6) | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ZBTB2 | c.53_56delinsC p.R18_E19delinsP | In Frame Del (DEL) | VAF 32/69 reads (46%) | called by pindel, varscan2*
- CLDN5 | c.282G>T p.A94= (on ENST00000618236 / NM_001363066.2; = p.A179= on NM_003277.4) | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- KLC3 | c.328C>A p.R110= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1273243780; called by muse, mutect2
- MYPN | c.219C>T p.D73= | Silent (SNP) | VAF 7/106 reads (7%) | catalogued as COSV100590588; called by muse, mutect2
- NLRC3 | c.597G>T p.P199= | Silent (SNP) | VAF 5/52 reads (10%) | catalogued as COSV57094314; called by muse, mutect2
- WSCD1 | c.591G>A p.G197= | Silent (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2
- CCDC40 | c.2832+451G>A | Intron (SNP) | VAF 26/301 reads (9%) | catalogued as rs1465180629; called by muse, varscan2
